Somatic mutation profile of tumor specimen MMRF_2564_1_BM_CD138pos (aliquot MMRF_2564_1_BM_CD138pos_T1_KHS5U_K15137) from MMRF case MMRF_2564, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.9 years (20,435 days).
Specimen MMRF_2564_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a223777a-8519-4a56-aa39-b71f9a87a196.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2564_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2564_1_PB_Whole_C3_KHS5U_K15136; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11df8816-f372-4737-85af-bf7838c06e53

The open-access MAF lists 66 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 19, Missense Mutation 17, Silent 8, Intron 8, 3'Flank 5, 5'Flank 3, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC6 | c.1018G>A p.V340I (on ENST00000392336; = p.V315I on NM_033415.4) | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs926125072; called by muse, mutect2, varscan2
- FRYL | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99978349; called by muse, mutect2, varscan2
- LGR5 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99877781; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs200813035; called by muse, mutect2, varscan2
- CCDC142 | c.53del p.P18Rfs*2 | Frame Shift Del (DEL) | VAF 94/229 reads (41%) | called by mutect2, pindel, varscan2
- DGKH | c.2578del p.W860Gfs*23 | Frame Shift Del (DEL) | VAF 60/89 reads (67%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.8671G>A p.D2891N | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HUWE1 | c.6545T>C p.I2182T | Missense Mutation (SNP) | VAF 38/39 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- HYKK | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- IGHV2-70D | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, varscan2
- IGLV4-60 | c.358_362del p.T120_*121del | Frame Shift Del (DEL) | VAF 26/28 reads (93%) | called by pindel*, varscan2
- JCAD | c.2812dup p.E938Gfs*25 | Frame Shift Ins (INS) | VAF 92/214 reads (43%) | called by mutect2, pindel, varscan2
- LDLRAD4 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPDZ | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NECAB2 | c.596+1G>A p.X199_splice | Splice Site (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PCDHB10 | c.333T>G p.D111E | Missense Mutation (SNP) | VAF 5/172 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); called by muse, mutect2
- PSAPL1 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 101/215 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASGRF2 | c.3667A>G p.T1223A | Missense Mutation (SNP) | VAF 140/332 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TMEM38B | c.271T>C p.Y91H | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM27 | c.335T>A p.M112K | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.59779G>A p.D19927N (on ENST00000591111; = p.D12503N on NM_003319.4) | Missense Mutation (SNP) | VAF 56/119 reads (47%) | PolyPhen benign (0.143); called by muse, mutect2, varscan2
- BCLAF1 | c.2670C>T p.D890= | Silent (SNP) | VAF 63/173 reads (36%) | catalogued as rs756639376; called by muse, mutect2, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as rs1233195687; called by muse, varscan2
- IGKV1-5 | c.312T>C p.D104= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs769384830; called by muse, mutect2, varscan2
- KHDRBS3 | c.705G>A p.V235= | Silent (SNP) | VAF 39/64 reads (61%) | called by muse, mutect2, varscan2
- KIF13B | c.4104G>A p.Q1368= | Silent (SNP) | VAF 27/195 reads (14%) | called by muse, mutect2, varscan2
- NLGN2 | c.1875C>T p.Y625= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs758643283, COSV57209427; called by muse, mutect2, varscan2
- OR2AE1 | c.843G>A p.T281= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs576165620, COSV60390662; called by muse, mutect2, varscan2
- TSC22D2 | c.1668T>C p.H556= | Silent (SNP) | VAF 66/174 reads (38%) | catalogued as rs1160345822; called by muse, mutect2, varscan2
- AC078899.4 | n.723A>G | RNA (SNP) | VAF 55/94 reads (59%) | catalogued as rs1393614557; called by muse, mutect2, varscan2
- ACTR3C | chr7:150245862 G>C | 3'Flank (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- ADAR | c.*2360G>C | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.1538+338T>C | Intron (SNP) | VAF 91/194 reads (47%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 66/133 reads (50%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, varscan2
- BCL7A | chr12:122021560 G>C | 5'Flank (SNP) | VAF 78/152 reads (51%) | catalogued as COSV55849496; called by muse, varscan2
- BOLL | c.352+1218A>T | Intron (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- BTG1 | c.*893A>T | 3'UTR (SNP) | VAF 26/46 reads (57%) | catalogued as rs763677370; called by muse, mutect2, varscan2
- C14orf132 | chr14:96087994 A>T | 3'Flank (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- CHRM3 | c.*4838G>T | 3'UTR (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- DENND4A | chr15:65660405 G>A | 3'Flank (SNP) | VAF 92/198 reads (46%) | catalogued as rs937019178; called by muse, mutect2, varscan2
- DSE | c.*760A>C | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- EPSTI1 | chr13:42886411 A>T | 3'Flank (SNP) | VAF 20/21 reads (95%) | called by muse, mutect2, varscan2
- FBXO21 | chr12:117143436 A>C | 3'Flank (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- GLB1L3 | c.1100-37_1100-36del | Intron (DEL) | VAF 20/75 reads (27%) | called by pindel, varscan2
- GRIPAP1 | c.109+51C>T | Intron (SNP) | VAF 6/84 reads (7%) | catalogued as rs782791207; called by muse, mutect2
- HSPD1 | c.969+18G>A | Intron (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- IFT81 | c.1188+5535A>G | Intron (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- IGSF5 | c.*328C>G | 3'UTR (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- IRF1 | c.*165C>A | 3'UTR (SNP) | VAF 33/90 reads (37%) | called by muse, mutect2, varscan2
- KCNN4 | c.1050-56T>C | Intron (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- LANCL2 | c.*877A>T | 3'UTR (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- LZTS1 | c.*1770G>A | 3'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- MBOAT1 | c.*185G>A | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- MED17 | c.*2111G>A | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- OVOL1 | c.*920T>C | 3'UTR (SNP) | VAF 102/214 reads (48%) | called by muse, mutect2, varscan2
- PRLR | c.*1996del | 3'UTR (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- PRRX1 | chr1:170663491 TAATTCTTAA>AATTCTTATT | 5'Flank (ONP) | VAF 7/30 reads (23%) | called by pindel, varscan2*
- PYGO1 | c.*7081C>A | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- SERPINB1 | c.*1246T>A | 3'UTR (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- SLC26A7 | c.*2644G>A | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- SLMAP | c.1336+365T>C | Intron (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- SRGAP1 | c.*590T>C | 3'UTR (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- STK4 | c.*3491G>A | 3'UTR (SNP) | VAF 31/87 reads (36%) | catalogued as rs1322072669; called by muse, mutect2, varscan2
- TMCO1 | c.*423del | 3'UTR (DEL) | VAF 26/78 reads (33%) | catalogued as rs35952900; called by mutect2, varscan2
- ZMYND10 | c.*241G>A | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
